Gene-level copy-number profile of tumor specimen TCGA-50-5944-01A from TCGA case TCGA-50-5944, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-50-5944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e3c1cb90-1622-4f51-9f30-b209b7bdf48d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5944-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7668f0e3-b914-4a94-96d4-4001ae08bd21

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 924; copy number 2: 7,040; copy number 3: 26,245; copy number 4: 20,431; copy number 5: 2,488; copy number 6: 1,111; copy number 7: 350; copy number 8: 775; copy number 9: 120; copy number 10: 45; copy number 11: 65; copy number 12: 25; copy number 14: 25; copy number 18: 12; copy number 20: 5; copy number 21: 25; copy number 22: 1; copy number 23: 6; copy number 24: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5944-01A-11D-1752-01): tumor purity 0.57, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–24,592,104, 27 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr21:10,328,411–15,346,738, 76 genes (broad region; genes not listed).
- chr21:16,574,718–17,500,824, 10 genes: AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,458 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:103,855,829–105,038,496, 27 genes, copy number 7 (within-gene range 2–7): AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2.
- chr2:106,487,364–106,544,297, 3 genes, copy number 7 (within-gene range 2–7): CD8B2, AC108868.2, AC108868.1.
- chr5:58,198–2,262,023, 79 genes, copy number 7–10 (broad region; genes not listed).
- chr5:9,628,997–10,057,807, 6 genes, copy number 23 (within-gene range 4–23): TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2.
- chr5:10,137,138–10,138,365, 1 gene, copy number 22: AC034229.1.
- chr5:13,553,654–16,192,709, 34 genes, copy number 12–24: NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6.
- chr5:18,704,433–19,234,487, 9 genes, copy number 7: LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:118,000,253–122,075,570, 45 genes, copy number 7 (within-gene range 3–7): LINC02208, LINC02148, LINC02216, AC114311.1, LINC02215, RNU7-34P, AC093206.1, DTWD2, PTMAP2, MIR1244-2, AC008629.1, RNU6-373P, AC008629.2, AC008629.3, DMXL1, AC118465.1, LAMTOR3P2, RNU6-701P, MIR5706, TNFAIP8, RN7SL174P, RNA5SP190, HSD17B4, AC010409.1, FABP5P6, FAM170A, TUBAP15, AC008550.1, AC008574.1, RNU6-718P, AC113418.1, PRR16, PRELID3BP8, RNU4-69P, AC114284.1, AC008565.1, AC113352.1, AC008568.1, AC010350.1, AC008568.2, RPL23AP44, AC106806.1, AC106806.2, FTMT, SRFBP1.
- chr5:123,344,890–131,008,742, 90 genes, copy number 7–11 (broad region; genes not listed).
- chr5:165,349,030–176,510,074, 188 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr5:178,884,715–181,342,213, 110 genes, copy number 8 (broad region; genes not listed).
- chr10:33,177,492–36,995,585, 52 genes, copy number 8 (within-gene range 3–8): NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2.
- chr10:37,135,237–37,135,343, 1 gene, copy number 8: RNU6-811P.
- chr11:167,784–252,984, 8 genes, copy number 9: BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10.
- chr17:47,522,942–63,900,879, 491 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:35,172,072–35,216,240, 1 gene, copy number 7 (within-gene range 2–7): PROCR.
- chr20:35,195,306–36,951,843, 65 genes, copy number 7 (broad region; genes not listed).
- chr20:37,021,743–37,021,984, 1 gene, copy number 7: RPS3AP3.
- chr20:53,255,979–56,786,087, 51 genes, copy number 7: AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:63,090,806–64,313,132, 80 genes, copy number 9 (broad region; genes not listed).
- chr21:26,466,209–29,630,751, 44 genes, copy number 9–18 (within-gene range 2–18): CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189, BACH1, GAPDHP14, BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3.
- chr21:36,748,626–36,990,236, 1 gene, copy number 10 (within-gene range 2–10): HLCS.
- chr21:36,851,911–39,726,085, 71 genes, copy number 10–21 (within-gene range 2–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
